Somatic mutation profile of tumor specimen 0DCS5A from CCDI case PBBMNX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.7 years (1,341 days).
Specimen 0DCS5A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5424354-b8d9-4a4e-a94a-df5f0c678063.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCS5D (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbb5a666-c6f5-42f6-ba19-2a20f437ddca

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 450/2049 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BMP10 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 363/1208 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs771100602, COSV54894135; called by muse, mutect2, varscan2
- PLCB2 | c.2098C>T p.R700C | Missense Mutation (SNP) | VAF 98/1158 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as rs1325011113, COSV53036702; called by muse, mutect2
- TESK2 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 82/735 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1227764599, COSV59158112; called by muse, mutect2, varscan2
- BRAF | c.1836C>T p.I612= (on ENST00000288602 / NM_001374244.1; = p.I572= on NM_004333.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 573/2602 reads (22%) | called by muse, mutect2, varscan2
